Gene-level copy-number profile of tumor specimen TCGA-CR-6493-01A from TCGA case TCGA-CR-6493, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 69.6 years (25,432 days).
Specimen TCGA-CR-6493-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.bda04aed-db07-49c0-b180-7c01a008fb07.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-6493-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1846c9d4-f78f-4021-9491-157f756752f4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 818; copy number 2: 6,159; copy number 3: 9,101; copy number 4: 38,490; copy number 5: 2,187; copy number 6: 2,798; copy number 7: 60; copy number 8: 105; copy number 9: 5; copy number 12: 5; copy number 15: 29; copy number 17: 61.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-6493-01A-11D-1869-01): tumor purity 0.67, ploidy 3.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 100 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:100,641,975–104,252,651, 66 genes, copy number 12–17 (broad region; genes not listed).
- chr22:16,961,936–17,070,675, 5 genes, copy number 9 (within-gene range 4–9): GAB4, AC006548.2, VN1R9P, CECR7, AC006946.2.
- chr22:21,697,536–22,215,270, 29 genes, copy number 15 (within-gene range 2–15): YPEL1, AP000553.9, RN7SL280P, AP000553.8, MAPK1, RNA5SP493, AC245452.1, PPM1F, PPM1F-AS1, TOP3B, PRAMENP, IGLVI-70, IGLV4-69, IGLVI-68, AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
